Gene-level copy-number profile of tumor specimen ALCH-B1R1-TTP1-A from ALCHEMIST case ALCH-B1R1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.9 years (22,244 days).
Specimen ALCH-B1R1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8c5e4268-3cec-46b0-aa83-5820006fef17.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1R1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/2080f630-71c0-4347-ad45-c11f2d771852

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 7,499; copy number 2: 50,103; copy number 3: 1,011; copy number 4: 94; copy number 5: 23; copy number 6: 15; copy number 7: 9; copy number 8: 3; copy number 9: 13; copy number 11: 4; copy number 13: 3; copy number 14: 3; copy number 18: 5; copy number 19: 2; copy number 20: 1; copy number 22: 3; copy number 26: 2; copy number 83: 6.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,275,223–1,280,420, 1 gene: LINC01786.
- chr1:1,317,581–1,318,689, 1 gene (within-gene range 0–4): AL139287.1.
- chr1:1,331,280–1,349,418, 3 genes: TAS1R3, DVL1, MIR6808.
- chr1:1,399,520–1,402,046, 1 gene (within-gene range 0–5): MRPL20-AS1.
- chr1:28,505,980–28,510,892, 3 genes (within-gene range 0–1): SNHG3, SNORA73A, SNORA73B.
- chr1:28,592,200–28,595,443, 1 gene (within-gene range 0–1): RAB42.
- chr1:28,812,142–28,871,267, 1 gene (within-gene range 0–2): OPRD1.
- chr2:91,617,160–91,659,972, 1 gene (within-gene range 0–1): LSP1P4.
- chr4:25,622,777–25,623,601, 1 gene: AC092436.1.
- chr4:165,016,458–165,041,749, 1 gene (within-gene range 0–1): TRIM60.
- chr4:165,026,261–165,046,280, 2 genes: AC106872.7, AC106872.6.
- chr4:187,970,273–187,971,284, 1 gene: AC108073.1.
- chr5:171,345,343–171,345,630, 1 gene: AC091980.1.
- chr6:111,046,868–111,047,521, 1 gene: GSTM2P1.
- chr7:74,289,407–74,405,935, 1 gene: CLIP2.
- chr7:74,606,913–74,633,884, 2 genes: AC211433.2, AC211433.3.
- chr7:74,843,754–74,897,835, 3 genes (within-gene range 0–2): STAG3L2, PMS2P5, Y_RNA.
- chr7:101,195,007–101,201,038, 1 gene: MOGAT3.
- chr7:101,218,165–101,224,190, 1 gene (within-gene range 0–3): ZNHIT1.
- chr7:101,269,938–101,273,715, 2 genes: RNU6-1104P, AC006329.1.
- chr7:101,388,868–101,389,080, 1 gene (within-gene range 0–1): AC004965.1.
- chr7:140,404,058–140,427,974, 1 gene (within-gene range 0–2): RAB19.
- chr8:54,130,582–54,130,860, 1 gene: Metazoa_SRP.
- chr8:69,987,415–69,987,697, 1 gene: SUMO2P20.
- chr14:18,333,726–18,412,264, 2 genes: CR383658.1, CR383658.2.
- chr14:18,588,274–18,602,129, 2 genes (within-gene range 0–1): CR383656.9, OR11H12.
- chr15:22,983,192–23,039,572, 1 gene: TUBGCP5.
- chr16:525,155–527,407, 1 gene: LINC00235.
- chr16:1,078,781–1,080,142, 1 gene: SSTR5.
- chr16:49,517,762–49,518,601, 1 gene (within-gene range 0–2): ADAM3B.
- chr17:9,244,666–9,244,897, 1 gene: AC005695.3.
- chr17:16,391,434–16,416,689, 2 genes (within-gene range 0–2): FTLP12, AC093484.2.
- chr17:81,387,415–81,390,319, 2 genes: AC110285.5, AC110285.2.
- chr19:531,760–542,092, 1 gene: CDC34.
- chr19:1,941,172–1,981,338, 2 genes (within-gene range 0–6): CSNK1G2, CSNK1G2-AS1.
- chr19:11,237,450–11,241,943, 1 gene (within-gene range 0–1): ANGPTL8.
- chr20:51,831,797–51,862,912, 1 gene: LINC01429.
- chr20:56,667,430–56,667,531, 1 gene: RNU6-1146P.
- chr21:7,744,962–8,454,792, 26 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr21:8,680,538–8,761,335, 3 genes: CR381572.2, CR381572.1, LINC01666.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 92 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,137,017–1,179,555, 6 genes, copy number 8–9 (within-gene range 2–9): LINC01342, MIR200B, MIR200A, MIR429, AL390719.2, TTLL10-AS1.
- chr1:1,203,508–1,214,153, 2 genes, copy number 7–20: TNFRSF18, TNFRSF4.
- chr1:1,242,446–1,246,722, 1 gene, copy number 22: C1QTNF12.
- chr1:1,280,436–1,311,677, 4 genes, copy number 5–18 (within-gene range 4–18): SCNN1D, ACAP3, MIR6726, PUSL1.
- chr1:1,352,689–1,361,777, 1 gene, copy number 9: MXRA8.
- chr1:1,401,909–1,422,691, 5 genes, copy number 5 (within-gene range 0–5): MRPL20, RN7SL657P, MRPL20-DT, ANKRD65, AL391244.1.
- chr1:1,430,539–1,442,882, 2 genes, copy number 22: LINC01770, VWA1.
- chr1:1,471,765–1,534,685, 2 genes, copy number 6–7: ATAD3B, ATAD3A.
- chr1:2,586,491–2,591,469, 1 gene, copy number 5 (within-gene range 2–5): PRXL2B.
- chr4:1,113,639–1,153,726, 3 genes, copy number 5 (within-gene range 4–5): AC092535.4, TMED11P, AC092535.1.
- chr5:946,315–956,520, 1 gene, copy number 6: AC122719.1.
- chr5:180,293,245–180,295,253, 1 gene, copy number 5: AC008610.1.
- chr7:1,459,937–1,464,008, 1 gene, copy number 7: AC102953.1.
- chr7:63,348,861–63,359,306, 4 genes, copy number 11 (within-gene range 2–11): AC006455.5, AC006455.2, AC006455.3, AC006455.4.
- chr7:74,906,673–74,913,310, 1 gene, copy number 8: SPDYE12P.
- chr8:12,194,467–12,196,280, 1 gene, copy number 13: AC145124.1.
- chr8:143,915,153–143,976,734, 2 genes, copy number 9 (within-gene range 9–10): PLEC, MIR661.
- chr8:144,051,266–144,063,965, 2 genes, copy number 19 (within-gene range 2–19): OPLAH, MIR6846.
- chr9:136,658,856–136,672,678, 2 genes, copy number 9 (within-gene range 2–9): EGFL7, MIR126.
- chr10:103,877,569–103,918,184, 1 gene, copy number 5 (within-gene range 2–5): STN1.
- chr11:1,242,261–1,249,676, 1 gene, copy number 8: MUC5B-AS1.
- chr11:1,389,899–1,462,689, 1 gene, copy number 6: BRSK2.
- chr11:1,584,342–1,585,283, 1 gene, copy number 7 (within-gene range 2–7): KRTAP5-1.
- chr11:1,607,565–1,608,463, 1 gene, copy number 5: KRTAP5-3.
- chr11:1,888,078–1,891,895, 1 gene, copy number 6 (within-gene range 6–9): PRR33.
- chr11:1,983,237–2,001,470, 6 genes, copy number 83 (within-gene range 1–83): MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr14:105,597,691–105,601,728, 1 gene, copy number 7 (within-gene range 5–7): IGHE.
- chr16:560,394–584,109, 4 genes, copy number 5: PRR35, PIGQ, NHLRC4, Z98883.1.
- chr16:629,239–636,366, 2 genes, copy number 18 (within-gene range 3–18): WFIKKN1, METTL26.
- chr16:649,311–667,833, 2 genes, copy number 7 (within-gene range 3–7): WDR90, AL022341.2.
- chr16:678,504–684,528, 4 genes, copy number 14–18 (within-gene range 3–18): LINC02867, Z92544.2, STUB1, JMJD8.
- chr16:1,101,260–1,221,771, 7 genes, copy number 6–26 (within-gene range 3–26): AL031713.1, AL031598.1, AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6.
- chr16:1,911,475–1,918,415, 1 gene, copy number 5: HS3ST6.
- chr16:2,513,965–2,527,955, 1 gene, copy number 6 (within-gene range 3–6): AC093525.1.
- chr16:2,520,357–2,532,005, 3 genes, copy number 6: AMDHD2, CEMP1, MIR3178.
- chr16:88,382,959–88,440,757, 1 gene, copy number 26: ZNF469.
- chr19:463,346–474,983, 1 gene, copy number 7: ODF3L2.
- chr19:1,228,287–1,239,522, 2 genes, copy number 5–13 (within-gene range 2–13): CBARP, AC004221.1.
- chr19:1,248,553–1,279,244, 4 genes, copy number 5–9: MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr20:62,513,909–62,516,096, 1 gene, copy number 5: AL499627.1.

Autosomal genes at a single copy (total copy number 1): 4,643. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
